Surgical pathology report (de-identified scan), TCGA case TCGA-EE-A2M5, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Sydney, specimen TCGA-EE-A2M5-06A (Metastatic).

[page 1 of 3]
Client History Upload External

DOB/Age/Sex:
Location:
Requested by:
Requested on:
Specimen Rcvd:
Accession No.:
Copies to:

ARCHIVAL HISTOPATHOLOGY SUPPLEMENTARY REPORT

Accession Number:

Collected Date:

SUPPLEMENTARY HISTORICAL REQUEST DETAIL

SUPPLEMENTARY REPORT

ADDENDUM REPORT

I. Special stains (x2) on the lymph node metastasis (Block F) are inconclusive but are consistent with a dedifferentiating malignant melanoma.

Positive : S100 (+ patchy including some nuclei)
Equivocal : Melan A (mainly nuclear staining)
: Cytokeratin (weak diffuse)

Electronic signature

ICD-0-3

Melanoma, NOS 8720/3

Site: lymph node, axillary

C29.3

hw 8/24/11

SUPPLEMENTARY SUMMARY / KEY WORDS

Axillary lymph node - malignant melanoma, metastatic

Printed:

[page 2 of 3]
Requested by: N/A

MRN/Nam
Locatio.
Accession:

ARCHIVAL HISTOPATHOLOGY REPORT

Accession Number:

Collected Date:

HISTORICAL REQUEST DETAILS

CLINICAL NOTES

Left axillary contents stitch marks highest node. Tumour left axilla.

SPECIMEN INFORMATION

Left axillary dissection for recurrent melanoma. Necrotic tumour mass.

MACROSCOPIC DESCRIPTION

Two specimens were received.

I. "Contents left axilla. Stitch marks highest node". An ellipse of hair-bearing skin 85 x 25mm, with underlying fatty tissue, tumour and skeletal muscle with an aggregate dimension of 150 x 85 x 75mm. The piece of skeletal muscle measures 95 x 35 x 18mm. Extending to the deep surface of the specimen is a disrupted tumour mass 105 x 55 x approximately 55mm. Assessing of the surgical margin in this area is not possible due to gross disruption. On sectioning the tumour has a variegated white, yellow, tan and haemorrhagic appearance. There is no macroscopic involvement of muscle or of the overlying skin.

- A. Apical node.
- B. 1 lymph node.
- C. 2 lymph nodes.
- D. 1 lymph node.
- E&F. Sections of large tumour mass.
- G. 1 lymph node.
- J. 1 lymph node.
- H. 3 lymph nodes.
- K&L. 1 lymph node.
- M. 1 lymph node.
- N. 1 lymph node.
- O. Muscle adjacent to tumour.
- P. Overlying skin.

II. "Tumour left axilla". Multiple haemorrhagic fragments of white and yellow tissue with an aggregate dimension of 30 x 15 x 6mm. Representative sections embedded in one block.

MICROSCOPIC REPORT

I. "Contents left axilla". The large tumour mass in fibroadipose tissue and two of the lymph nodes (Blocks H and N) show high grade malignant tumour consistent with metastatic melanoma.

II. "Tumour left axilla". Malignant tumour similar to specimen I, in

[page 3 of 3]
Requested by: N/A

MRN/Name:

Location:

Accession:

ARCHIVAL HISTOPATHOLOGY REPORT

Accession Number:

Collected Date:

fibroadipose tissue.

Electronic signature

IMMUNOHISTOCHEMISTRY REPORT

Immunoperoxidase stains: To follow.

Please see addendum report.

SUMMARY / KEY WORDS

Lymph node, axillary - malignant melanoma, metastatic
Haematopathology resection

Source: NCI Genomic Data Commons file 1d625d4d-42fd-49ca-afee-501fc29e58ad (TCGA-EE-A2M5.00A02AC4-3B9A-4FA0-B0B7-EA8307FF17E1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).